Somatic mutation profile of tumor specimen TCGA-WZ-A7V3-01A (aliquot TCGA-WZ-A7V3-01A-11D-A435-10) from TCGA case TCGA-WZ-A7V3, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 20.1 years (7,325 days).
Specimen TCGA-WZ-A7V3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae576a33-0cf4-46ad-b324-017d58c5cdb7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-WZ-A7V3-10A (Blood Derived Normal), aliquot TCGA-WZ-A7V3-10A-01D-A438-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/335d4eeb-4d09-4aef-9cd0-23324638f01b

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 9, Silent 2, Frame Shift Del 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPWD1 | c.665A>G p.H222R | Missense Mutation (SNP) | VAF 64/182 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776437383; called by muse, mutect2, varscan2
- SGTB | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV101121568, COSV66818556; called by muse, mutect2, varscan2
- ZZEF1 | c.1838C>T p.A613V | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.884); catalogued as rs759910798, COSV104431387; called by muse, mutect2, varscan2
- ALG9 | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- BIRC6 | c.5285C>T p.A1762V | Missense Mutation (SNP) | VAF 107/518 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ERICH6 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- KIAA1586 | c.1880T>A p.I627N | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- RNF213 | c.5784_5792dup p.C1930_D1931insEVC | In Frame Ins (INS) | VAF 12/64 reads (19%) | called by mutect2, varscan2
- RNF8 | c.580G>A p.E194K | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SACS | c.8658C>G p.H2886Q | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SPAG1 | c.1561_1562del p.M521Efs*11 | Frame Shift Del (DEL) | VAF 13/102 reads (13%) | called by mutect2, pindel, varscan2
- ITGA4 | c.1233G>A p.S411= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs368002151; called by muse, mutect2, varscan2
- ZNF233 | c.1704G>T p.V568= | Silent (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
